Somatic mutation profile of tumor specimen MP2PRT-PASXZH-TMP1-A (aliquot MP2PRT-PASXZH-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PASXZH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,182 days).
Specimen MP2PRT-PASXZH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf4d91ff-6e68-40f8-9c0b-3e62f9c6a858.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASXZH-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASXZH-NM1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/785b1fcb-4f0c-41ae-8aeb-f5c7a2c80125

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPI | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 232/623 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs151137290; called by muse, mutect2, varscan2
- CACTIN | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 237/512 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.325); catalogued as rs201581975; called by muse, mutect2, varscan2
- DOCK6 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 100/275 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs546562962, COSV53915240, COSV53923608; called by muse, mutect2, varscan2
- ERG | c.1109A>G p.D370G (on ENST00000398919 / NM_001243428.1; = p.D346G on NM_004449.4) | Missense Mutation (SNP) | VAF 221/561 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55729043; called by muse, mutect2, varscan2
- HEG1 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 149/343 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs747607775; called by muse, mutect2, varscan2
- ACR | c.730C>T p.L244F | Missense Mutation (SNP) | VAF 23/606 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- TRAJ48 | chr14:22490487 TGTGTATCTAACTTTG>CCT | Missense Mutation (DEL) | VAF 79/112 reads (71%) | called by pindel, varscan2*
- CAVIN2 | c.1098G>A p.S366= | Silent (SNP) | VAF 19/690 reads (3%) | catalogued as COSV58424323, COSV58424403; called by muse, mutect2
- SATB2 | c.1473C>A p.I491= | Silent (SNP) | VAF 188/439 reads (43%) | called by muse, mutect2, varscan2
- IGHV1-58 | chr14:106627248 ins CCCCTCGGA | 5'Flank (INS) | VAF 30/68 reads (44%) | called by mutect2, varscan2
- IGKV1D-43 | chr2:90210529 ins CC | 3'Flank (INS) | VAF 79/235 reads (34%) | called by mutect2, pindel, varscan2
